Surgical pathology report (de-identified scan), TCGA case TCGA-BC-4073, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-4073-01B (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Number :

1CD-0-3
carcinoma, hepatocellular, NOS
8170/3

Collection Date :

site: liver C22-0
7/5/11

Collected:

Received:

Completed:

Surgical Pathology Report

Diagnosis:

A: Lymph node, portal, excision

- No metastatic carcinoma identified in one lymph node (0/1)

- Intraoperative diagnosis confirmed

B: Liver, left lobe, Segments 1-4, partial hepatectomy

Tumor histologic type: Hepatocellular carcinoma

Histologic grade (Edmonson \T\ Steiner classification):
Grade 3-4 out of 4 (moderately to poorly differentiated)

Tumor size, focality and extent: Multiple tumor nodules ranging from 0.5 cm to 3.5 cm in diameter are present throughout the specimen, comprising approximately 50% of the overall specimen volume; overall tumor size more than 5.0 cm

Necrosis: Present; approximately 40 % of the total tumor volume is necrotic (status post radiofrequency ablation)

Pattern of growth: Solid and trabecular growth patterns

Venous invasion: Extensively present; tumor thrombus present in large portal vein branch at resection margin and extensive microscopic intravascular tumor foci throughout the specimen

Perforation of peritoneum: Not identified

[page 2 of 5]
Surgical margins: Positive; hepatocellular carcinoma present in multiple portal vein branches (grossly and microscopically) at the resection margin (slides B11, B13)

Non-neoplastic liver: - Patchy parenchymal iron deposition (1-2+) by iron stain
- Moderate fibrosis (stage 2-3) but no obvious cirrhosis seen by Trichrome stain
- Moderate mixed micro- and macrovesicular steatosis involving approximately 10% of the total liver volume

Regional lymph nodes: None received with this specimen (see also portal lymph node above, specimen A)

AJCC Stage: pT3 pN0 pMx

Note: This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

C: Gallbladder, cholecystectomy
- Chronic cholecystitis with cholelithiasis

Intraoperative Consult Diagnosis:
An intraoperative consultation was requested by Dr.

FSA1: "Portal lymph node," excision
- No tumor seen

Frozen Section Pathologist:

Clinical History:
left hepatic lobe lesions (Segments 2 and 3). The patient has a history of right lobe HCC. Status post radiofrequency ablation. The patient also has questionable history of hemochromatosis.

Gross Description:
Received are three appropriately labeled containers.

Container A is additionally labeled "portal lymph node." It holds a 1.7 x 1.2 x 0.5 cm red/tan soft tissue fragment.

[page 3 of 5]
BLOCK: FSB1 - Frozen section remnant, entirely submitted
B1-B2 - Remainder of specimen, entirely submitted

Specimen C was additionally labeled "segment 5 and 6, liver". The specimen consists of a partial hepatectomy that weighs 400 grams and measures 12.0 x 10.0 x 4.0 cm. The external surface is tan/brown and has multiple variable sized nodules that measure up to 4.5 cm. In addition, a central focus of cavitation is noted that measures 3.0 x

3.0 cm across and 2.8 cm in depth, which is consistent with a possible previous biopsy. The area of resection is inked black prior to sectioning. The specimen is sequentially sectioned at 1.5 cm thick cross sections. On cut section, the nodules are tan/gray, well circumscribed, and have multifocal patchy areas of pale yellow softening. The closest nodule extends to within 2.0 cm of the inked surgical margin of resection. Elsewhere, the parenchyma is tan/brown and has a lobular appearance.

Block Summary:

- C1 - Representative section of nodule closest to surgical margin
- C2 - Representative additional sections of surgical margin
- C3 - Representative section of tumor and unremarkable parenchyma
- C4 - Representative section of tumor nodule with pale yellow discoloration

Specimen D is received in one appropriately labeled container, additionally labeled "porta hepatis mass". The specimen consists of a 5.6 x 3.8 x 2.2 cm unoriented tan/brown soft tissue fragment. The entire outer surface of the specimen is inked blue. The specimen is serially sectioned and the cut surface reveals a tan/white-circumscribed nodule with central softening and hemorrhage, consistent with necrosis. The mass occupies the entire specimen. Representative sections are submitted in cassettes D1-D3.

Specimen E is additionally labeled "segment 3 liver biopsy".

[page 4 of 5]
One candidate lymph node was identified that measures 1.2 x 1.0 x 0.5 cm. It is submitted as FSA1. The remainder of fibroadipose tissue is submitted as A1,

Container B:

Specimen Type: lobectomy (Segments 1-4)

Specimen Weight: 700 grams

Measurement: 15 x 13 x 6.5 cm; There is a roughened surface marked with a long suture. This was inked black and represents the medial margin of the partial hepatectomy specimen. There is a second cut surface which is smooth and is inked blue. No designation of surgical margins was included with the specimen.

Mass: There are multiple soft-firm tan, white nodules diffusely spread throughout the lateral half of the specimen. Tumor is estimated to involve 60% of liver parenchyma. Diameter of nodules ranges from 0.5-3.5 cm. Tumor is located 0.5 cm from blue inked margin and 1.5 cm from black inked margin. No discrete nodules are present in the medial half of the specimen (near the black inked margin), but there appears to be involvement by tumor of the vascular spaces in this region.

Adjacent liver tissue: The remainder of liver parenchyma appears normal. No fibrosis is evident.

Capsule: appears thickened and is nodular

Major portal vein/ hepatic vein: gross evidence of vascular invasion (major portal vein and other smaller vascular spaces in the medial half of the specimen) is present

Gallbladder: submitted as Specimen C

Block summary:

- B1-B2 - portal triad vascular margins
- B3 - portal vein with black inked margin
- B4 - tumor with blue inked margin
- B5-B6 - representative sections of tumor
- B7 - tumor with capsule
- B8 - tumor with adjacent uninvolved liver parenchyma
- B9 - tumor with involvement of vasculature
- B10-B13 - representative sections of black inked margin, en

[page 5 of 5]
face

B14 - uninvolved liver parenchyma

Container C:

Previously opened: no

Measurements: 7.5 x 3.0 x 1.6 cm

External surface: pink/tan with a roughened hepatic surface

Wall thickness: 2-4 mm

Mucosa: red and granular with adherent black granular material and multiple firm

black stones

Stones present: measuring from 2 to 6 mm; black/tan and firm and angulated

Other comments: none

Block #: C1

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr.

Source: NCI Genomic Data Commons file c34d1070-7fce-448d-bb18-1b6f04a001a5 (TCGA-BC-4073.1C53BF2E-0AA8-477F-8281-63455E0D36E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).